Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6AQ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6AQ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY:

PROCEDURE DATE:

RECEIVED DATE:

REPORT DATE:

COPY TO: . [REDACTED] . [REDACTED]

C&CF

ICD-O-3

Adenocarcinoma of the Prostate 8140/3

path
Adenocarcinoma NOS 8140/3

Site Prostate C61.9

JW 5/16/13

Pre-Op Diagnosis
Prostate cancer
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:

Received in a single container labeled [REDACTED] - prostate" is a previously inked, previously sectioned moderately distorted prostate gland with attached bilateral seminal vesicles. The specimen is received after tissue harvest for genomic study. Within the specimen container are three tissue cassettes labeled

The specimen in the intact state weighs 67 grams with the prostate gland measuring 5.5 x 5.0 x 5.0 cm. This has a lobulated focally shaggy outer surface with prominent verumontanum at the base. The urethra is 3.2 x 0.5 x 0.2 cm and patent with evidence of compression by the lateral lobes. The cut surface reveals multinodular gray tan to pink fibrotic cut surface with focal nodular areas having a slight yellow discoloration. These are scattered through both lateral lobes in the mid to proximal (basal) regions as well as focally extending to the posterior lobes on both sides. A single discrete gross lesion is not identified. A few of the chalky yellow appearing regions extend focally to within 0.1 cm of the nearest inked surfaces. The seminal vesicles together are 5.6 x 3.2 x 1.2 cm. These have lobulated tan pink outer surfaces with areas of fragmentation. On sectioning there is a multicystic gray tan fibrotic cut surface. No gross lesions are identified. Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe

[page 2 of 2]
distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle.

Microscopic Description:
Reviewed are slides labeled [REDACTED]

Final Diagnosis

Prostate, prostatectomy:

Tumor characteristics:

Histologic type: Adenocarcinoma.

Prostate size: 76 grams, 5.5 x 5.0 x 5.0 cm.

Tumor quantitation: Tumor involves approximately 5% of total tissue volume.

Gleason grade:

Primary pattern: 3/5

Secondary pattern: 4/5

Total Gleason score: 7/10

Extraprostatic extension: Not identified (see comment).

Seminal vesicle involvement: Not identified.

Lymphovascular space invasion: Not identified.

High grade PIN: Present.

Treatment effect: Not applicable.

Surgical margin status:

See comment.

Lymph node status:

Not applicable.

Other:

pTN stage: pT2c Nx PAS 9 SPC-A

Comments

Histologic sections demonstrate adenocarcinoma extending up to the surface of the specimen along the left posterior lobe mid region. While definitive evidence of tumor transection is not identified, this area is highly suspicious for extension of the neoplasm beyond the plane of surgical resection. Further, while no extraprostatic extension is identified in the sections examined, clinical correlation and correlation with intraoperative findings is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

MPAA Discrepancy		✓

Source: NCI Genomic Data Commons file dcc19c83-fdef-4420-893b-5c2542a9688f (TCGA-HC-A6AQ.1B1D93C4-54AB-43CA-B800-6807A81AA89A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).